Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8YT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8YT-01A (Primary Tumor).

[page 1 of 2]
Patient Name: [REDACTED]
DOB: [REDACTED]

MRN: [REDACTED]
Patient ID: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3

Carcinoma, squamous cell
NOS 8070/3

Date Cervix NOS
C53.9

11/17/14

SURGICAL PATHOLOGY REPORT * Consult Report *

FINAL

Patient Name: [REDACTED]	Service: [REDACTED]	Accession #: [REDACTED]
Address: [REDACTED]	Location: [REDACTED]	Taken: [REDACTED]
Gender: F	MRN: [REDACTED]	Received: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])	Hospital #: [REDACTED]	Accessioned: [REDACTED]
	Patient Type: [REDACTED]	Reported: [REDACTED]
Physician(s): [REDACTED]		

DIAGNOSIS

CERVIX, BIOPSY

- POORLY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA (SEE COMMENT)
- LYMPHOVASCULAR INVASION IS PRESENT
- TUMOR INVADES TO A DEPTH OF AT LEAST 6 MM AND EXTENDS TO THE DEEP EDGE OF THE TISSUE

ENDOCERVIX, CURETTAGE

- DETACHED FRAGMENTS OF DYSPLASTIC SQUAMOUS EPITHELIUM
- FRAGMENTS OF BENIGN ENDOCERVICAL TISSUE

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material) reviewed in the diagnosis.

***Report Electronically Reviewed and Signed Out By [REDACTED]

Microscopic Description and Comment:

Sections of the cervical biopsy show invasive squamous cell carcinoma. The invading cells are arranged in small nests and show large nuclei, pale-staining chromatin, and nucleoli. Intercellular bridges are seen among some of the cells. Mitotic activity is frequent. The invasive tumor is found beneath unremarkable squamous epithelium. One piece of the biopsy shows focal koilocytic atypia and mild dysplasia (CIN1) involving the surface; however is not connected to the squamous carcinoma.

Sections of the endocervical curettage material show, in addition to benign endocervical tissue, small, detached fragments of dysplastic squamous epithelium. Because the fragments are small, poorly-oriented, and not associated with stroma, it is impossible to grade the dysplasia.

Selected slides were reviewed at the [REDACTED]

[page 2 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

History:

The patient is a [REDACTED] year old woman with low grade squamous intraepithelial lesion on PAP smear.

Materials Received:

Received are two slides labeled [REDACTED] and sublabeled A1 and B1. These slides are derived from an endocervical curettage (A) and cervical biopsy (B) performed [REDACTED] accompanying [REDACTED] corresponding pathology report. The material originates from [REDACTED] One slide is scanned, and the material is returned to the referring institution.

END OF REPORT

Page 2 of 2

Page: 2 of 2

Source: NCI Genomic Data Commons file 322248d3-f5cb-4fea-8f7f-c6a9a1051059 (TCGA-C5-A8YT.78E3AF70-E5A9-4A7F-ABD1-4E08238EAB9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).